Somatic mutation profile of tumor specimen TCGA-DE-A3KN-01A (aliquot TCGA-DE-A3KN-01A-11D-A20C-08) from TCGA case TCGA-DE-A3KN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 49.5 years (18,098 days).
Specimen TCGA-DE-A3KN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 741095fe-c8c3-41fc-a273-dac94d9bd8ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A3KN-10A (Blood Derived Normal), aliquot TCGA-DE-A3KN-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4b1652f-db8c-4ecd-9a9e-8deea2dabd70

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK7 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs767517486, COSV52015601; called by muse, mutect2, varscan2
- DYNC1H1 | c.12503G>A p.R4168Q | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs1468120172, COSV64140098; called by muse, mutect2, varscan2
- HMOX2 | c.654G>C p.R218S | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV54861161; called by muse, mutect2, varscan2
- LRRC55 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV73006821; called by muse, mutect2, varscan2
- PLXNB1 | c.4978C>G p.L1660V | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56492539; called by muse, mutect2, varscan2
- VCAN | c.2566C>G p.L856V | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV54112256; called by muse, mutect2, varscan2
- KAAG1 | c.171C>T p.S57= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV51239913; called by muse, mutect2
